Somatic mutation profile of tumor specimen TCGA-CD-A487-01A (aliquot TCGA-CD-A487-01A-21D-A24D-08) from TCGA case TCGA-CD-A487, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 51.2 years (18,694 days).
Specimen TCGA-CD-A487-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad0a3d0b-968f-4938-97ce-e3a468326d08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-A487-10A (Blood Derived Normal), aliquot TCGA-CD-A487-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69137537-e6dc-4ebc-8b99-c27ed091fe03

The open-access MAF lists 189 somatic variants for this specimen: 146 protein-altering or splice-affecting, 42 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 42, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABR | c.2476G>A p.D826N (on ENST00000302538 / NM_021962.5; = p.D789N on NM_001092.5) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1318020920, COSV52147173; called by muse, varscan2
- ADGRV1 | c.7435T>C p.F2479L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as COSV67987608; called by muse, mutect2, varscan2
- AP2B1 | c.1284C>G p.I428M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as COSV52000366, COSV99251749; called by muse, mutect2, varscan2
- ARNT | c.1999G>A p.V667M | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.005); catalogued as COSV62231025; called by muse, mutect2, varscan2
- BCKDHA | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.959); catalogued as rs1188940806, COSV54197749; called by muse, mutect2, varscan2
- BPIFB6 | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs754691183, COSV62755544; called by muse, mutect2, varscan2
- CASC3 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.141); catalogued as COSV52866508; called by muse, varscan2
- CASC3 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV52866516; called by muse, mutect2
- CCNE1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 36/684 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52904781, COSV52905919; called by muse, mutect2
- CD7 | c.149C>A p.T50N | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV53939716; called by muse, mutect2, varscan2
- CELF4 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.154); catalogued as rs777172664, COSV58446360; called by muse, mutect2, varscan2
- CEP152 | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs374221404; called by muse, mutect2
- CEP290 | c.5230C>G p.L1744V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58352749; called by muse, mutect2, varscan2
- CEP76 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as rs1428274796, COSV50867241; called by muse, mutect2, varscan2
- CFAP47 | c.1174A>G p.S392G | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.611); catalogued as COSV52886455, COSV52894132; called by muse, varscan2
- CFAP58 | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV63834575; called by muse, mutect2, varscan2
- CLEC5A | c.160A>C p.S54R | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV69397426; called by muse, mutect2, varscan2
- COL18A1 | c.3614G>A p.R1205Q (on ENST00000359759 / NM_130444.3; = p.R970Q on NM_030582.4) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs768453031, COSV60589777; called by muse, mutect2, varscan2
- COL1A2 | c.3897A>C p.E1299D | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1562908882, CD1411945, COSV51959936; called by muse, mutect2, varscan2
- COL20A1 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs376817042; called by muse, mutect2, varscan2
- CSE1L | c.139T>A p.L47M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV53702564; called by muse, mutect2
- CSMD1 | c.4318T>G p.F1440V (on ENST00000520002; = p.F1439V on NM_033225.6) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100142201, COSV59314221; called by muse, mutect2, varscan2
- CTCFL | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1211625769, COSV54775528; called by muse, mutect2, varscan2
- CYGB | c.347A>C p.K116T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); catalogued as COSV53150398; called by muse, mutect2, varscan2
- CYP7B1 | c.1253T>G p.F418C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59590705; called by muse, mutect2
- DCAF15 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as COSV54330638; called by muse, mutect2, varscan2
- DDX54 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs200999538; called by muse, mutect2, varscan2
- DNAH9 | c.7267G>T p.D2423Y | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs757516746, COSV52335706, COSV52355161; called by muse, mutect2, varscan2
- DRAP1 | c.471A>T p.Q157H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV56988894; called by muse, mutect2, varscan2
- DYNC2H1 | c.3973G>A p.V1325I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.145); catalogued as rs1043262932, COSV62096667; called by muse, mutect2
- EIF4B | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs778266609, COSV50403735; called by muse, mutect2, varscan2
- ELAPOR2 | c.2110T>G p.F704V (on ENST00000450689 / NM_001142749.3; = p.F537V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51887016; called by muse, mutect2, varscan2
- EML2 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV55600546; called by muse, mutect2, varscan2
- EPN3 | c.1561A>G p.K521E | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV52140489; called by muse, mutect2, varscan2
- ESRRG | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100752664, COSV63165500; called by muse, mutect2, varscan2
- FAM83F | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs531840891, COSV61000099; called by muse, mutect2, varscan2
- FLG2 | c.2996A>G p.Y999C | Missense Mutation (SNP) | VAF 84/391 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV66169466; called by muse, mutect2, varscan2
- FOLH1 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57050739; called by muse, mutect2, varscan2
- FSHR | c.779A>C p.K260T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV58625816; called by muse, mutect2
- GABRA5 | c.70T>G p.L24V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs576861235, COSV59475453; called by muse, mutect2, varscan2
- GDPGP1 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as rs200606347, COSV61575839; called by muse, mutect2, varscan2
- GLYR1 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs1156637655, COSV58927448; called by muse, mutect2, varscan2
- GRIA1 | c.2680A>T p.S894C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.75); catalogued as COSV53607778, COSV99598242; called by muse, mutect2, varscan2
- GRM3 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.292); catalogued as COSV64470358; called by muse, mutect2, varscan2
- HDGFL1 | c.29A>T p.K10M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57752225; called by muse, mutect2
- HK3 | c.2599G>A p.D867N | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52838243, COSV52841287; called by muse, mutect2, varscan2
- IFI16 | c.1489T>G p.L497V | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.087); catalogued as COSV55535266; called by muse, mutect2, varscan2
- IGSF1 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.15); catalogued as COSV100812144; called by muse, mutect2, varscan2
- IVL | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV64216195; called by muse, mutect2
- KCTD8 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs1280175125, COSV63590566; called by muse, mutect2
- KIAA1109 | c.5641A>G p.I1881V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV52677776; called by muse, mutect2, varscan2
- LPAR3 | c.98T>G p.V33G | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.226); catalogued as COSV65453920; called by muse, mutect2, varscan2
- LPO | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV51859808; called by muse, mutect2, varscan2
- LRRIQ3 | c.1343T>G p.V448G | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV63045172; called by muse, mutect2, varscan2
- LRRK2 | c.1835A>G p.Y612C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54156725; called by muse, mutect2, varscan2
- MAGEC3 | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV53581791, COSV74217448; called by muse, mutect2, varscan2
- MPPED1 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs749308599, COSV68837855, COSV68838445; called by muse, mutect2, varscan2
- MTMR11 | c.1289A>T p.E430V (on ENST00000439741 / NM_001145862.2; = p.E358V on NM_181873.3) | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV54965797; called by muse, mutect2, varscan2
- MYO18B | c.7327G>A p.D2443N | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV59137447; called by muse, mutect2, varscan2
- MYT1 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs759933398, COSV60507396; called by muse, mutect2, varscan2
- NAP1L2 | c.1269A>C p.E423D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as COSV65172619; called by muse, mutect2, varscan2
- NAV1 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759712759, COSV55219290; called by muse, mutect2, varscan2
- NEXMIF | c.4452A>C p.K1484N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV50022095; called by muse, varscan2
- NEXMIF | c.2288T>G p.V763G | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV50040294; called by muse, mutect2, varscan2
- OR10J5 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV58386422; called by muse, mutect2, varscan2
- OR13A1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65572648; called by muse, mutect2, varscan2
- OR2D2 | c.162A>C p.Q54H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs766531079, COSV55057423; called by muse, mutect2, varscan2
- OR2G3 | c.127T>G p.F43V | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60681689; called by muse, mutect2, varscan2
- OR4P4 | c.314T>G p.F105C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV58922405; called by muse, mutect2, varscan2
- OR51L1 | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV58624389; called by muse, mutect2, varscan2
- OR5L1 | c.712T>G p.F238V | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1565118470, COSV61734280; called by muse, mutect2, varscan2
- OSBPL2 | c.883C>T p.L295F (on ENST00000313733 / NM_144498.4; = p.L283F on NM_014835.4) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV58217189; called by muse, mutect2
- PCDH15 | c.4719A>T p.E1573D | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.955); catalogued as COSV64702250; called by muse, mutect2, varscan2
- PCDHB3 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 52/367 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV50564677, COSV50581609; called by muse, mutect2, varscan2
- PCSK1 | c.437T>G p.L146R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100227142; called by muse, mutect2, varscan2
- PDSS1 | c.197C>A p.S66Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.289); catalogued as rs1159086264, COSV66058976; called by muse, mutect2, varscan2
- PDZD8 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1237291780, COSV57826275; called by muse, mutect2, varscan2
- PHRF1 | c.2689G>A p.G897R (on ENST00000264555 / NM_001286581.2; = p.G896R on NM_020901.4) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs746823568, COSV52757191; called by muse, mutect2, varscan2
- PIEZO2 | c.7046C>T p.A2349V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53290651; called by muse, mutect2, varscan2
- PKHD1L1 | c.3938G>C p.W1313S | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.191); catalogued as COSV65745344; called by muse, mutect2, varscan2
- PLXNA2 | c.2284T>C p.C762R | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV65441669; called by muse, mutect2, varscan2
- PNN | c.393T>A p.D131E | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.12); catalogued as COSV53766992, COSV53768571; called by muse, mutect2, varscan2
- POLH | c.884+1G>C p.X295_splice | Splice Site (SNP) | VAF 6/36 reads (17%) | catalogued as COSV64779820; called by muse, mutect2, varscan2
- PPP1R12B | c.1449C>A p.N483K | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV61118600; called by muse, mutect2, varscan2
- PPRC1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs773022710, COSV53383190; called by muse, mutect2, varscan2
- PREX2 | c.3898A>C p.T1300P | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV55777486; called by muse, mutect2, varscan2
- PSAT1 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs377282696, COSV61302918; called by muse, mutect2, varscan2
- PTCHD1 | c.1621T>C p.Y541H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV65061192; called by muse, mutect2, varscan2
- PTPRC | c.1357A>C p.T453P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61413734; called by muse, mutect2
- RANBP3 | c.1682G>A p.G561E (on ENST00000340578 / NM_007322.3; = p.G556E on NM_003624.3) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs1303189651, COSV50382690; called by muse, mutect2, varscan2
- RASGRP3 | c.1691C>A p.P564H (on ENST00000402538 / NM_001349975.2; = p.P563H on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67821714; called by muse, mutect2, varscan2
- RTP2 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.978); catalogued as COSV64078812, COSV64079133; called by muse, mutect2, varscan2
- RYR3 | c.2942T>G p.I981S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as COSV66794685; called by muse, mutect2, varscan2
- RYR3 | c.4933G>T p.D1645Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV66794690; called by muse, mutect2, varscan2
- SCN3A | c.37A>G p.S13G | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs1419143735, COSV51813268; called by muse, mutect2, varscan2
- SELP | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs767813249, COSV55253485; called by muse, mutect2, varscan2
- SEMA4G | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV52969042; called by muse, mutect2, varscan2
- SLC18A3 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as COSV60320455; called by muse, mutect2, varscan2
- SLC37A2 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs573542470, COSV53522220; called by muse, mutect2, varscan2
- SOX5 | c.551A>C p.N184T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV58633726; called by muse, mutect2, varscan2
- SPEF2 | c.3417G>T p.W1139C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61549200; called by muse, mutect2, varscan2
- SPTA1 | c.226T>G p.L76V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63748768, COSV63754867; called by muse, mutect2, varscan2
- SPTLC3 | c.1114A>C p.S372R | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100982890, COSV65464481; called by muse, mutect2, varscan2
- STAB2 | c.1700A>C p.K567T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as COSV66340893; called by muse, mutect2, varscan2
- SYNE1 | c.13859T>G p.L4620R (on ENST00000367255 / NM_182961.4; = p.L4549R on NM_033071.3) | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55009012; called by muse, mutect2, varscan2
- SYNE2 | c.8083G>T p.G2695* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV59954452; called by muse, mutect2, varscan2
- TAS2R14 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV67857087; called by muse, mutect2, varscan2
- TAS2R7 | c.372G>C p.W124C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV53689167; called by muse, mutect2, varscan2
- TBX18 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV63737192; called by muse, mutect2, varscan2
- TENM4 | c.5534G>A p.R1845H | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs760270892, COSV53637431; called by muse, mutect2, varscan2
- THAP9 | c.2692G>A p.D898N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs755384363, COSV56356702; called by muse, mutect2, varscan2
- TMEM87A | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.19); catalogued as COSV56198182; called by muse, mutect2
- TRAPPC4 | c.176T>A p.V59E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57723010; called by muse, varscan2
- TRIM42 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766965674, COSV53883946; called by muse, mutect2, varscan2
- TRIML2 | c.466C>A p.Q156K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as COSV58717159; called by muse, mutect2, varscan2
- TRO | c.1696C>A p.P566T | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51502757; called by muse, mutect2, varscan2
- TRPC4 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59003521; called by muse, mutect2, varscan2
- TRPS1 | c.215A>C p.K72T (on ENST00000220888 / NM_001330599.2; = p.K85T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV55246319; called by muse, mutect2, varscan2
- TSPAN11 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.02); catalogued as rs746170702, COSV53819185; called by muse, mutect2, varscan2
- TTC3 | c.2833T>C p.Y945H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1255496741, COSV61291656; called by muse, mutect2, varscan2
- TTN | c.59929T>C p.S19977P (on ENST00000591111; = p.S12553P on NM_003319.4) | Missense Mutation (SNP) | VAF 32/215 reads (15%) | PolyPhen probably damaging (0.919); catalogued as COSV60128588; called by muse, mutect2, varscan2
- TTN | c.44903A>G p.Q14968R (on ENST00000591111; = p.Q7544R on NM_003319.4) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | PolyPhen benign (0.033); catalogued as COSV60128627; called by muse, mutect2, varscan2
- TTN | c.3893A>C p.K1298T (on ENST00000591111; = p.K1252T on NM_003319.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | PolyPhen probably damaging (0.997); catalogued as COSV100617507; called by muse, mutect2
- USH2A | c.11651A>G p.E3884G | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV56384634; called by muse, mutect2, varscan2
- VANGL2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1314974864, CM114448, COSV63604698; called by muse, mutect2, varscan2
- VIP | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV65888792, COSV65889145; called by muse, mutect2, varscan2
- VPS13A | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62431743; called by muse, mutect2, varscan2
- WEE1 | c.1697A>G p.H566R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV55197486; called by muse, mutect2, varscan2
- WWP1 | c.2548G>C p.V850L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55360356; called by muse, mutect2, varscan2
- XIRP2 | c.2496A>C p.E832D (on ENST00000628543; = p.E1007D on NM_152381.6) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54687255; called by muse, mutect2, varscan2
- ZC3H15 | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV100552118; called by muse, mutect2, varscan2
- ZFP42 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770512257, COSV58817829; called by muse, mutect2, varscan2
- ZNF208 | c.1331A>C p.K444T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs757778735, COSV68107888, COSV68112550; called by muse, mutect2, varscan2
- ZNF354A | c.112T>G p.L38V | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV59983672; called by muse, mutect2, varscan2
- ZNF385D | c.358T>C p.S120P | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55759857; called by muse, mutect2, varscan2
- ZNF408 | c.647G>C p.C216S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV61238474; called by muse, mutect2, varscan2
- ZNF677 | c.281T>G p.F94C | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as COSV61720472; called by muse, mutect2, varscan2
- ZNF804A | c.2443A>C p.K815Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV56453369; called by muse, mutect2
- ZNF804B | c.903A>C p.K301N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV60832487; called by muse, varscan2
- ZNF804B | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV60832494; called by muse, varscan2
- C5orf24 | c.385del p.T129Lfs*39 | Frame Shift Del (DEL) | VAF 16/142 reads (11%) | called by mutect2, varscan2
- CDC42BPA | c.3336del p.K1112Nfs*22 (on ENST00000334218 / NM_001366019.2; = p.K1099Nfs*22 on NM_003607.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | called by mutect2, pindel, varscan2
- LEPROTL1 | c.124dup p.Y42Lfs*17 | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | called by mutect2, varscan2
- NSFL1C | c.796dup p.Q266Pfs*15 | Frame Shift Ins (INS) | VAF 21/194 reads (11%) | called by mutect2, pindel, varscan2
- RASSF10 | c.1465_1468del p.L489Afs*74 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- ADAM33 | c.1155C>T p.F385= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1339275201, COSV62935168; called by muse, mutect2, varscan2
- AMIGO1 | c.462C>T p.F154= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as rs749853651, COSV63990258; called by muse, mutect2, varscan2
- ATAD5 | c.4776G>A p.L1592= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV58975611; called by muse, mutect2, varscan2
- CASC3 | c.1881C>T p.V627= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as COSV52866494; called by muse, varscan2
- CDH23 | c.9993C>T p.S3331= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs540139281, COSV56470537; called by muse, mutect2, varscan2
- CHST8 | c.1245C>T p.N415= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1209992077, COSV52859801; called by muse, mutect2, varscan2
- CILP | c.3495G>A p.Q1165= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV56025052; called by muse, mutect2, varscan2
- CNTN3 | c.2103A>G p.E701= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV55162308, COSV55174437; called by muse, mutect2, varscan2
- COL14A1 | c.1398G>T p.V466= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV52857844; called by muse, mutect2, varscan2
- CRYBA4 | c.132G>A p.V44= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV61322192; called by muse, mutect2, varscan2
- CSN3 | c.543G>A p.T181= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs753060878, COSV59244296; called by muse, mutect2, varscan2
- DCAF12L1 | c.1164C>T p.S388= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs1218461875, COSV64422005; called by muse, mutect2, varscan2
- DOCK4 | c.4896G>A p.P1632= | Silent (SNP) | VAF 70/182 reads (38%) | catalogued as rs1274497749, COSV70238413; called by muse, mutect2, varscan2
- DSEL | c.3093A>G p.G1031= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV59492278; called by muse, mutect2, varscan2
- KDM3A | c.3309T>G p.A1103= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV57222114; called by muse, mutect2, varscan2
- KRTAP13-3 | c.273T>A p.S91= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV61879462, COSV61879897, COSV61880010; called by muse, mutect2, varscan2
- MAB21L3 | c.843C>T p.S281= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV65674017; called by muse, mutect2
- MTMR8 | c.480C>G p.T160= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs928180902, COSV66394479; called by muse, mutect2
- NEFH | c.1902C>A p.S634= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV60218003; called by muse, varscan2
- NEUROD4 | c.12T>G p.T4= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV54471636; called by mutect2, varscan2
- NPR1 | c.2661G>A p.A887= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as rs141781853; ClinVar: likely benign; called by muse, mutect2, varscan2
- NXPE4 | c.162C>T p.F54= | Silent (SNP) | VAF 43/186 reads (23%) | catalogued as COSV64943924; called by muse, mutect2, varscan2
- OCA2 | c.1935C>T p.G645= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs763989326, COSV100668987, COSV62348406; called by muse, mutect2
- OR1C1 | c.726C>T p.S242= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV68715834; called by muse, mutect2, varscan2
- OR2T6 | c.744G>A p.V248= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV63216030; called by muse, mutect2, varscan2
- OR5V1 | c.669C>T p.S223= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV65828436; called by muse, mutect2, varscan2
- OR8G2P | c.736T>C p.L246= | Silent (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- PLEC | c.3699C>T p.R1233= (on ENST00000322810 / NM_201380.4; = p.R1123= on NM_000445.5) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs370987177; called by muse, mutect2, varscan2
- PPARGC1A | c.1074C>G p.L358= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV53529014; called by muse, mutect2, varscan2
- PPBP | c.78G>C p.L26= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV56019885; called by muse, mutect2, varscan2
- RBP3 | c.417G>A p.P139= | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as rs782585106; called by muse, mutect2, varscan2
- SALL3 | c.2307G>T p.T769= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV73306072, COSV73306132; called by muse, mutect2, varscan2
- SPAG16 | c.1674C>T p.I558= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs376387182; called by muse, mutect2, varscan2
- STPG2 | c.1141A>C p.R381= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV54802849, COSV54803241; called by muse, mutect2, varscan2
- SUN2 | c.24C>T p.L8= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV53304653; called by muse, mutect2, varscan2
- TAF15 | c.1602C>T p.D534= (on ENST00000605844 / NM_139215.3; = p.D531= on NM_003487.4) | Silent (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- TLR9 | c.3075C>T p.F1025= | Silent (SNP) | VAF 41/199 reads (21%) | catalogued as COSV62347232; called by muse, mutect2, varscan2
- TMPRSS6 | c.2205C>T p.R735= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV60977903; called by muse, mutect2, varscan2
- TRHR | c.594C>A p.V198= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100304892; called by muse, mutect2
- TTN | c.5841T>C p.P1947= (on ENST00000591111; = p.P1901= on NM_003319.4) | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as COSV60128661; called by muse, mutect2, varscan2
- ZNF197 | c.2223G>A p.K741= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV60360775, COSV60361815; called by muse, mutect2, varscan2
- ZNF454 | c.1317T>G p.P439= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV60768904; called by muse, mutect2, varscan2
- DHRS4L1 | n.112T>C | RNA (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
